Somatic mutation profile of tumor specimen TCGA-FZ-5924-01A (aliquot TCGA-FZ-5924-01A-13D-1609-08) from TCGA case TCGA-FZ-5924, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 83.7 years (30,571 days).
Specimen TCGA-FZ-5924-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd0a18ea-acc3-4228-848e-2f8ca4c3257a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5924-11A (Solid Tissue Normal), aliquot TCGA-FZ-5924-11A-01D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ab91c1c-4c3c-4845-9288-b75bb953d32c

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 13, Frame Shift Ins 2, Nonsense Mutation 2, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs786205753, CM133184, COSV59697881; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 22/176 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 65/283 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67960494; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 74/251 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO6 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 172/523 reads (33%) | catalogued as rs774784458, COSV57662863; called by muse, mutect2, varscan2
- B3GAT1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs753312357, COSV56997082; called by muse, mutect2, varscan2
- BRF1 | c.576C>A p.H192Q | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as COSV100526747; called by muse, mutect2, varscan2
- CR2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 94/592 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs201791442; called by muse, mutect2, varscan2
- DHTKD1 | c.1675A>G p.R559G | Missense Mutation (SNP) | VAF 223/982 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535957; called by muse, mutect2, varscan2
- EBF3 | c.1517C>T p.S506L (on ENST00000355311 / NM_001375392.1; = p.S497L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/723 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs750469936, COSV100798977; called by muse, mutect2, varscan2
- GPT2 | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 169/696 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100412757, COSV100413160; called by muse, mutect2, varscan2
- HRC | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53256372, COSV99417465; called by muse, mutect2, varscan2
- IGKV2D-28 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs1340777156; called by mutect2, varscan2
- KLHL40 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.383); catalogued as COSV99825295; called by muse, mutect2, varscan2
- MMP16 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 114/484 reads (24%) | catalogued as COSV99685685; called by muse, mutect2, varscan2
- MYEOV | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 91/703 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100456559; called by muse, mutect2, varscan2
- PLCE1 | c.2473A>G p.K825E | Missense Mutation (SNP) | VAF 122/451 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV53363472; called by muse, mutect2, varscan2
- PLXDC2 | c.1338G>C p.E446D | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV101022676; called by muse, mutect2, varscan2
- PXDN | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs755575492, COSV53233112; called by muse, mutect2, varscan2
- SHC4 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 153/603 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as COSV100194130; called by muse, mutect2, varscan2
- SLC22A11 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 311/1153 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs774607500; called by muse, mutect2, varscan2
- SLC9A3R2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs367680143; called by muse, mutect2, varscan2
- SPTB | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 114/430 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs149837193; called by muse, mutect2, varscan2
- TAF2 | c.84-2A>G p.X28_splice | Splice Site (SNP) | VAF 61/220 reads (28%) | catalogued as rs746816527, COSV100558210; called by muse, mutect2, varscan2
- XIRP2 | c.1550T>C p.V517A (on ENST00000628543; = p.V692A on NM_152381.6) | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.069); catalogued as COSV99737675; called by muse, mutect2, varscan2
- ZMYM3 | c.551_552insT p.Q185Tfs*8 | Frame Shift Ins (INS) | VAF 98/252 reads (39%) | catalogued as COSV100077391; called by mutect2, pindel, varscan2
- KIAA0895 | c.1068dup p.H357Tfs*2 (on ENST00000297063 / NM_001100425.2; = p.H306Tfs*2 on NM_015314.3) | Frame Shift Ins (INS) | VAF 128/582 reads (22%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.2306_2309del p.L769Pfs*49 | Frame Shift Del (DEL) | VAF 87/403 reads (22%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.3153T>C p.D1051= | Silent (SNP) | VAF 129/471 reads (27%) | catalogued as COSV101062865; called by muse, mutect2, varscan2
- ARNT2 | c.699G>A p.S233= | Silent (SNP) | VAF 92/447 reads (21%) | catalogued as rs767002088, COSV57586156; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A1 | c.2097C>T p.G699= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs537366421, COSV62613973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYTN | c.258G>A p.P86= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs747863949, COSV101510795; called by muse, mutect2, varscan2
- FZD10 | c.330C>T p.C110= | Silent (SNP) | VAF 32/652 reads (5%) | catalogued as rs745641282, COSV99969184; called by muse, mutect2
- IL31RA | c.1590C>A p.T530= | Silent (SNP) | VAF 141/768 reads (18%) | catalogued as COSV99762748; called by muse, mutect2, varscan2
- KRT39 | c.195T>C p.F65= | Silent (SNP) | VAF 223/1028 reads (22%) | catalogued as COSV100842158; called by muse, mutect2, varscan2
- PC | c.837C>T p.P279= | Silent (SNP) | VAF 88/562 reads (16%) | catalogued as rs369972881; called by muse, mutect2, varscan2
- PCARE | c.1353G>A p.G451= | Silent (SNP) | VAF 134/539 reads (25%) | catalogued as rs767747198, COSV100527259, COSV100527522; called by muse, mutect2, varscan2
- PPP2R5A | c.81A>G p.K27= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as COSV99806389; called by muse, mutect2, varscan2
- PTCHD3 | c.1041C>T p.L347= | Silent (SNP) | VAF 357/1455 reads (25%) | catalogued as rs1334226042, COSV71256873; called by muse, mutect2, varscan2
- TERT | c.2541C>T p.G847= | Silent (SNP) | VAF 78/373 reads (21%) | catalogued as rs770543108, COSV57215455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDBF2 | c.2952G>A p.K984= | Silent (SNP) | VAF 81/350 reads (23%) | catalogued as COSV100984300, COSV65629827; called by muse, mutect2, varscan2
- SLC35A2 | c.1163+137C>T | Intron (SNP) | VAF 29/50 reads (58%) | catalogued as COSV99504016; called by muse, mutect2, varscan2
- SNAP25 | c.164-268C>T | Intron (SNP) | VAF 98/464 reads (21%) | catalogued as rs146976467, COSV54770758; called by muse, mutect2, varscan2
